Somatic mutation profile of tumor specimen TARGET-10-PASSPP-09A (aliquot TARGET-10-PASSPP-09A-01D) from TARGET case TARGET-10-PASSPP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,642 days).
Specimen TARGET-10-PASSPP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30d28552-4729-4814-81a4-bfe9091dd436.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASSPP-10A (Blood Derived Normal), aliquot TARGET-10-PASSPP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0742571c-a47b-4aed-929f-492338d310d3

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Silent 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.16847del p.P5616Lfs*87 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs1428656669, COSV100317479; called by mutect2, pindel, varscan2
- GEM | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771063860, COSV52599511; called by muse, varscan2
- HECTD4 | c.8533C>A p.L2845M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.847); catalogued as COSV66402460; called by muse, mutect2
- MDN1 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV65533430; called by muse, mutect2, varscan2
- NOTCH1 | c.4847T>A p.I1616N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53028112; called by muse, mutect2, varscan2
- PCDHAC1 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as COSV53875413; called by muse, mutect2, varscan2
- PTEN | c.703dup p.E235Gfs*8 | Frame Shift Ins (INS) | VAF 9/71 reads (13%) | catalogued as COSV100909324, COSV64297357, COSV64297592, COSV64297854, COSV64298139, COSV64299249, COSV64299822, COSV64300977, COSV64301275, COSV64303258, COSV64307832, COSV64308010, COSV99058022; called by mutect2, pindel, varscan2
- PZP | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV54373420; called by muse, mutect2, varscan2
- SLC4A5 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 28/47 reads (60%) | catalogued as COSV61034924; called by muse, mutect2, varscan2
- CSN3 | c.378G>A p.Q126= | Silent (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- FNDC1 | c.2046C>A p.R682= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV51931138; called by muse, mutect2, varscan2
- CTSF | c.1322-48C>T | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- HTR2A | c.412+61C>T | Intron (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2
- HYDIN | c.7158+2323G>T | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- RCC1L | c.*103C>T | 3'UTR (SNP) | VAF 3/9 reads (33%) | catalogued as rs1018788802; called by muse, mutect2
- SLC22A6 | c.-4C>A | 5'UTR (SNP) | VAF 10/31 reads (32%) | catalogued as rs537423039; called by muse, mutect2, varscan2
